Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-AA6I, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-AA6I-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Gastroesophageal junction C16.0
JW 3/20/14

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Gastroesophageal junction)

"Esophagus + stomach":

- . Poorly differentiated adenocarcinoma, invasive and ulcerated
- . Size of the neoplasm: 7.0 x 4.7 x 2.4cm (2.4cm deep)
- . Location: esophagogastric transition
- . Depth of infiltration: up to subserosa
- . Sanguineous vascular invasion: not detected
- . Lymphatic vascular invasion: present
- . Perineural invasion: present
- . Adjacent gastric mucosa: intense active chronic gastritis
- . Omentum :
- Mature adipose tissue free neoplasia
- Presence of 1 lymph node free of tumor (0/1)
- . Surgical margins free of neoplastic involvement
- . 15 lymph nodes were dissected, of which 9 are compromised by neoplasia (9/15), with capsular leakage, and distributed as follows:
- Peri-tumoral nodes: 1/2
- Nodes from lesser curvature: 8/10
- Nodes from greater curvature: 0/3

"Esophageal margin":

- . Free of neoplasia

"Terminal ileum + ascending colon":

- . Ileal and colonic mucosa within normal limits
- . Appendix: no histological particularities
- . 6 lymph nodes were dissected from the adjacent fat, all free of tumor (0/6)

"Gallbladder":

- . Intense chronic cholecystitis

Source: NCI Genomic Data Commons file c03c5f6a-6ad2-4bfc-bea9-b8487a31a50d (TCGA-VQ-AA6I.7DE61CB4-1A8A-4FF9-A26C-5740D2758C96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).